CPTAC case C3L-02858 — Kidney — Lipomatous Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Lipomatous Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/af85d94e-6352-4baf-9fc4-9dc8d7ded612

Demographics
Sex at birth: female; Race: white; Year of birth: 1977; Vital status: Alive.

Diagnoses (1)
1. Angiomyolipoma: ICD-O-3 morphology code: 8860/0; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 39.8 years (14,545 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: MX; Tumor grade: GX; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 2,343 days (6.4 years); Progression or recurrence: no; Days to last follow up: 2,343 days (6.4 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5.8 cm; Margin status: Indeterminate; Sarcomatoid present: No.

Follow-up (4 entries)
- Days to follow up: 487 days (1.3 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 834 days (2.3 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 834 days (2.3 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,296 days (3.5 years); Disease response: With Tumor; Karnofsky performance status: 100; ECOG performance status: 0.

Other clinical attributes
- Weight: 40.91 kg; Height: 150.11 cm; BMI: 18.15.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Cigarettes per day: 25; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02858-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 240 mg; Time between excision and freezing: 12 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02858-21: Section location: Upper pole; Percent tumor nuclei: 95; Percent necrosis: 0.
- Sample C3L-02858-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
